Somatic mutation profile of tumor specimen MP2PRT-PAPZGC-TMP1-A (aliquot MP2PRT-PAPZGC-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPZGC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,202 days).
Specimen MP2PRT-PAPZGC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18b0faca-e6f0-4fc7-bae2-1f1080d93ed8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZGC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZGC-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ed39118-d7f6-41e9-8075-3aa7fe0485c1

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 92/316 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL15A1 | c.3770A>G p.H1257R | Missense Mutation (SNP) | VAF 108/320 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.501); catalogued as rs756057838; called by muse, mutect2, varscan2
- TAP2 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 85/294 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs773291187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMC2 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 89/293 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs749890793, COSV62651886; called by muse, mutect2, varscan2
- VTCN1 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.913); catalogued as COSV60224923; called by muse, mutect2, varscan2
- CDKAL1 | c.32_47delinsTACCGGCC p.D11Vfs*14 | Frame Shift Del (DEL) | VAF 73/303 reads (24%) | called by pindel, varscan2*
- DPP4 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 56/214 reads (26%) | called by muse, mutect2, varscan2
- LIFR | c.1397G>A p.C466Y | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS9 | c.3654C>T p.D1218= | Silent (SNP) | VAF 121/377 reads (32%) | catalogued as COSV55782119; called by muse, mutect2, varscan2
- SNRPB2 | c.81A>G p.L27= | Silent (SNP) | VAF 63/223 reads (28%) | catalogued as rs531994011; called by muse, mutect2, varscan2
- TGS1 | c.1812T>A p.T604= | Silent (SNP) | VAF 88/283 reads (31%) | called by muse, mutect2, varscan2
